CCDI case PBBVHG — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/ad9fef33-bafb-4460-b4dc-c589b67cb258

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Neoplasm, uncertain whether benign or malignant: ICD-O-3 morphology code: 8000/1; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 15.8 years (5,787 days).

Biospecimens (3 samples)
- Sample 0DI3J0: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DI3JH: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DI3M1: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
